Somatic mutation profile of tumor specimen MMRF_2728_1_BM_CD138pos (aliquot MMRF_2728_1_BM_CD138pos_T1_KHS5U_L14867) from MMRF case MMRF_2728, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow.
Specimen MMRF_2728_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 50555a3b-92e4-4857-85d3-05be99139d04.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2728_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2728_1_PB_WBC_C3_KHS5U_L14868; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/098f1332-084e-4dd6-b52d-b864ddc39800

The open-access MAF lists 105 somatic variants for this specimen: 44 protein-altering or splice-affecting, 17 silent, 44 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, 3'UTR 30, Silent 17, Intron 7, Nonsense Mutation 3, 5'UTR 3, 5'Flank 2, Splice Region 1, In Frame Del 1, RNA 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1517G>T p.G506V (on ENST00000288602 / NM_001374244.1; = p.G466V on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs121913351, CM115083, COSV56057462, COSV56059390, COSV56070593; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADGRA2 | c.1222C>T p.R408C | Missense Mutation (SNP) | VAF 61/127 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs1357273209; called by muse, mutect2, varscan2
- ANO1 | c.2675C>T p.A892V | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs767390604; called by muse, mutect2, varscan2
- ASXL3 | c.6512T>C p.I2171T | Missense Mutation (SNP) | VAF 69/172 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.357); catalogued as rs746016958; called by muse, mutect2, varscan2
- CAMK4 | c.400G>A p.G134R | Missense Mutation (SNP) | VAF 60/263 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56668920, COSV56684990; called by muse, mutect2, varscan2
- DIP2C | c.4624T>G p.F1542V | Missense Mutation (SNP) | VAF 95/218 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV55175925; called by muse, mutect2, varscan2
- FUT2 | c.982C>T p.P328S | Missense Mutation (SNP) | VAF 51/187 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs769915216; called by muse, mutect2, varscan2
- GRM6 | c.1501-7G>A | Splice Region (SNP) | VAF 24/169 reads (14%) | catalogued as rs375581430; called by muse, mutect2, varscan2
- IGLV3-1 | c.322G>A p.A108T | Missense Mutation (SNP) | VAF 28/141 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.009); catalogued as rs541322241; called by muse, mutect2, varscan2
- IL36RN | c.220C>T p.Q74* | Nonsense Mutation (SNP) | VAF 21/59 reads (36%) | catalogued as rs368461730; called by muse, mutect2, varscan2
- KANK4 | c.2696C>T p.A899V | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1269267384; called by muse, mutect2
- OBSCN | c.22655G>A p.R7552Q | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.066); catalogued as rs373096072; called by muse, mutect2
- OR2M3 | c.269A>C p.K90T | Missense Mutation (SNP) | VAF 150/276 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0.049); catalogued as COSV71758987, COSV71759018; called by muse, mutect2, varscan2
- RANBP17 | c.2144G>A p.R715H | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.902); catalogued as rs371474320; called by muse, mutect2, varscan2
- SPTBN2 | c.1768G>A p.V590I | Missense Mutation (SNP) | VAF 63/169 reads (37%) | SIFT tolerated (0.39); PolyPhen benign (0.416); catalogued as rs780059779, COSV59446318; called by muse, mutect2, varscan2
- SRRM3 | c.1826G>A p.R609H | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.005); catalogued as rs1344816735; called by muse, mutect2, varscan2
- TIAM1 | c.1858C>T p.R620C | Missense Mutation (SNP) | VAF 63/216 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs753525414, COSV54552084; called by muse, mutect2, varscan2
- XRN2 | c.1250G>A p.R417Q | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.812); catalogued as rs1262828363, COSV65869359; called by muse, mutect2, varscan2
- ZEB1 | c.1669C>T p.Q557* | Nonsense Mutation (SNP) | VAF 64/169 reads (38%) | catalogued as COSV100314747; called by muse, mutect2, varscan2
- CD300LD | c.19C>A p.L7M | Missense Mutation (SNP) | VAF 107/296 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CHD1 | c.218A>G p.K73R | Missense Mutation (SNP) | VAF 17/287 reads (6%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); called by muse, mutect2
- CHD8 | c.2296G>T p.D766Y (on ENST00000646647 / NM_001170629.2; = p.D487Y on NM_020920.4) | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CYLD | c.2159A>G p.E720G | Missense Mutation (SNP) | VAF 5/104 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.089); called by muse, mutect2
- DNAH11 | c.2132C>T p.A711V | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- DNAH2 | c.1453G>A p.V485M | Missense Mutation (SNP) | VAF 8/135 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); called by muse, mutect2
- DNAH2 | c.5536G>A p.A1846T | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- EPHA2 | c.1090G>T p.V364F | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- GOLGB1 | c.814G>A p.A272T | Missense Mutation (SNP) | VAF 55/224 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- HAO1 | c.266A>G p.D89G | Missense Mutation (SNP) | VAF 56/132 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.312); called by muse, mutect2, varscan2
- IRAG2 | c.3052T>C p.S1018P (on ENST00000636465; = p.S63P on NM_006152.4 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 132/384 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0.017); called by muse, mutect2
- LRRC8A | c.154A>C p.M52L | Missense Mutation (SNP) | VAF 14/324 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.012); called by muse, mutect2
- NRXN3 | c.241G>A p.G81R | Missense Mutation (SNP) | VAF 3/52 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.498); called by muse, mutect2
- PEG3 | c.2713C>T p.Q905* | Nonsense Mutation (SNP) | VAF 87/282 reads (31%) | called by muse, mutect2, varscan2
- SERPINB11 | c.1070A>T p.K357I | Missense Mutation (SNP) | VAF 62/147 reads (42%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, mutect2
- SH3GL2 | c.731_733del p.I244del | In Frame Del (DEL) | VAF 11/47 reads (23%) | called by mutect2, pindel, varscan2
- SIK2 | c.442C>G p.L148V | Missense Mutation (SNP) | VAF 20/179 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2
- SOX15 | c.418A>C p.N140H | Missense Mutation (SNP) | VAF 42/107 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- SPEF2 | c.5465A>T p.K1822I | Missense Mutation (SNP) | VAF 54/248 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.486); called by muse, mutect2, varscan2
- TRAPPC2B | c.277G>A p.D93N | Missense Mutation (SNP) | VAF 61/254 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- TSPAN19 | c.147T>A p.N49K | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.52); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- UBAP2 | c.2870G>A p.G957D | Missense Mutation (SNP) | VAF 9/209 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.439); called by muse, mutect2
- USP54 | c.3741T>G p.D1247E | Missense Mutation (SNP) | VAF 54/136 reads (40%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- XKR9 | c.137G>A p.S46N | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT tolerated (0.33); PolyPhen benign (0.377); called by muse, mutect2, varscan2
- ZKSCAN5 | c.1697A>G p.Q566R | Missense Mutation (SNP) | VAF 10/182 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.157); called by muse, mutect2
- ATAD2 | c.1596A>G p.E532= | Silent (SNP) | VAF 71/221 reads (32%) | catalogued as COSV99784113; called by muse, mutect2, varscan2
- CROCC | c.276C>T p.R92= | Silent (SNP) | VAF 20/97 reads (21%) | catalogued as rs201548237; called by muse, mutect2, varscan2
- DMD | c.321T>A p.T107= | Silent (SNP) | VAF 18/21 reads (86%) | catalogued as CD100288; called by muse, mutect2, varscan2
- EGFR | c.939C>T p.A313= | Silent (SNP) | VAF 72/181 reads (40%) | called by muse, mutect2, varscan2
- FBLIM1 | c.27G>A p.V9= | Silent (SNP) | VAF 30/95 reads (32%) | catalogued as rs1479891876; called by muse, mutect2, varscan2
- HK3 | c.1989C>T p.D663= | Silent (SNP) | VAF 76/310 reads (25%) | called by muse, mutect2, varscan2
- JPH2 | c.1086C>T p.V362= | Silent (SNP) | VAF 24/361 reads (7%) | catalogued as COSV100881540; called by muse, mutect2
- NKX3-2 | c.453C>T p.S151= | Silent (SNP) | VAF 14/32 reads (44%) | called by muse, mutect2
- PCDHA13 | c.1461C>T p.N487= | Silent (SNP) | VAF 11/63 reads (17%) | catalogued as rs572170960, COSV99165907; called by muse, mutect2, varscan2
- PCF11 | c.162C>A p.I54= | Silent (SNP) | VAF 61/157 reads (39%) | called by muse, mutect2, varscan2
- PGC | c.345C>T p.F115= | Silent (SNP) | VAF 23/74 reads (31%) | called by muse, mutect2, varscan2
- SLC16A7 | c.1401A>C p.A467= | Silent (SNP) | VAF 32/116 reads (28%) | called by muse, mutect2, varscan2
- TMEM51 | c.711G>A p.P237= | Silent (SNP) | VAF 35/90 reads (39%) | catalogued as rs765815480; called by muse, mutect2, varscan2
- TMEM9B | c.186T>C p.S62= | Silent (SNP) | VAF 17/59 reads (29%) | called by muse, mutect2, varscan2
- TTN | c.92832A>G p.P30944= (on ENST00000591111; = p.P23520= on NM_003319.4) | Silent (SNP) | VAF 43/116 reads (37%) | called by muse, mutect2, varscan2
- XRCC1 | c.576C>T p.F192= | Silent (SNP) | VAF 24/78 reads (31%) | called by muse, mutect2, varscan2
- ZNF268 | c.786G>A p.S262= | Silent (SNP) | VAF 163/411 reads (40%) | catalogued as rs758134250, COSV57212678; called by muse, mutect2, varscan2
- ADD3 | c.*1867dup | 3'UTR (INS) | VAF 28/67 reads (42%) | called by mutect2, pindel, varscan2
- AFF1 | c.*4878G>C | 3'UTR (SNP) | VAF 46/123 reads (37%) | catalogued as rs1194952594; called by muse, mutect2, varscan2
- AHNAK | c.*770T>A | 3'UTR (SNP) | VAF 20/41 reads (49%) | called by muse, mutect2, varscan2
- APLP1 | c.292-116G>A | Intron (SNP) | VAF 25/73 reads (34%) | catalogued as rs371521094; called by muse, mutect2, varscan2
- ATG9A | c.*832del | 3'UTR (DEL) | VAF 56/166 reads (34%) | called by mutect2, pindel, varscan2
- ATP6V1G3 | c.*22A>G | 3'UTR (SNP) | VAF 114/309 reads (37%) | catalogued as COSV55279955; called by muse, mutect2, varscan2
- BCAT1 | c.*3194A>G | 3'UTR (SNP) | VAF 10/20 reads (50%) | called by muse, mutect2
- BCAT1 | c.*2987A>G | 3'UTR (SNP) | VAF 32/80 reads (40%) | called by muse, mutect2, varscan2
- BMP6 | c.*104_*110del | 3'UTR (DEL) | VAF 13/64 reads (20%) | called by mutect2, pindel, varscan2
- C2orf68 | c.226+442T>A | Intron (SNP) | VAF 16/31 reads (52%) | catalogued as rs927520451; called by muse, mutect2, varscan2
- C9orf152 | c.*527G>A | 3'UTR (SNP) | VAF 20/98 reads (20%) | called by muse, mutect2, varscan2
- CCP110 | c.*1296A>G | 3'UTR (SNP) | VAF 6/17 reads (35%) | called by muse, mutect2, varscan2
- COPS2 | c.*1103G>A | 3'UTR (SNP) | VAF 21/100 reads (21%) | called by muse, mutect2, varscan2
- COX15 | c.-10T>C | 5'UTR (SNP) | VAF 96/262 reads (37%) | catalogued as rs770106452; called by muse, mutect2, varscan2
- D2HGDH | c.*687C>T | 3'UTR (SNP) | VAF 47/134 reads (35%) | catalogued as rs1056471627; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DMP1 | c.*598G>A | 3'UTR (SNP) | VAF 5/111 reads (5%) | called by muse, mutect2
- ETV7 | c.307+11C>T | Intron (SNP) | VAF 45/212 reads (21%) | catalogued as rs1011146668; called by muse, mutect2, varscan2
- GLE1 | c.*978C>T | 3'UTR (SNP) | VAF 18/67 reads (27%) | catalogued as rs1481444756; called by muse, mutect2, varscan2
- GOLGA4 | c.-368G>A | 5'UTR (SNP) | VAF 11/256 reads (4%) | called by muse, mutect2
- HOXA9 | c.*577del | 3'UTR (DEL) | VAF 32/122 reads (26%) | catalogued as rs1320471834; called by mutect2, pindel, varscan2
- ILKAP | c.299-13C>T | Intron (SNP) | VAF 34/85 reads (40%) | catalogued as rs1287239703; called by muse, mutect2, varscan2
- KLHL6 | c.*1658G>C | 3'UTR (SNP) | VAF 28/123 reads (23%) | called by muse, mutect2, varscan2
- MBLAC2 | c.-342G>A | 5'UTR (SNP) | VAF 108/182 reads (59%) | called by muse, mutect2, varscan2
- MDGA1 | c.*6351G>A | 3'UTR (SNP) | VAF 45/141 reads (32%) | called by muse, mutect2, varscan2
- MDM4 | c.*2519del | 3'UTR (DEL) | VAF 4/26 reads (15%) | called by mutect2, pindel, varscan2
- MPDZ | c.*1116G>A | 3'UTR (SNP) | VAF 32/107 reads (30%) | catalogued as rs939080766; called by muse, mutect2, varscan2
- OR7C1 | c.*6397C>T | 3'UTR (SNP) | VAF 24/132 reads (18%) | called by muse, mutect2, varscan2
- ORAI2 | c.*3647G>A | 3'UTR (SNP) | VAF 73/198 reads (37%) | called by muse, mutect2, varscan2
- PFKM | chr12:48105999 C>T | 5'Flank (SNP) | VAF 16/44 reads (36%) | called by muse, mutect2, varscan2
- POLR2M | c.*578C>T | 3'UTR (SNP) | VAF 101/368 reads (27%) | catalogued as rs183695117; called by muse, mutect2, varscan2
- PRMT8 | c.418-870G>C | Intron (SNP) | VAF 4/79 reads (5%) | called by muse, mutect2
- PTBP2 | c.*1408G>A | 3'UTR (SNP) | VAF 39/114 reads (34%) | called by muse, mutect2, varscan2
- ROBO2 | c.*44G>T | 3'UTR (SNP) | VAF 11/378 reads (3%) | called by muse, mutect2
- SARS1 | c.1257+279C>G | Intron (SNP) | VAF 33/90 reads (37%) | catalogued as rs745648414, COSV52320703; called by muse, mutect2, varscan2
- SLC6A5 | c.*3290T>G | 3'UTR (SNP) | VAF 30/64 reads (47%) | called by muse, mutect2, varscan2
- SLITRK2 | chrX:145827682 A>T | 3'Flank (SNP) | VAF 15/20 reads (75%) | called by muse, mutect2, varscan2
- SP7 | c.*239G>T | 3'UTR (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2
- SPTBN4 | c.5915+213T>C | Intron (SNP) | VAF 15/53 reads (28%) | catalogued as rs1232158662; called by muse, mutect2, varscan2
- TEX21P | n.1327T>G | RNA (SNP) | VAF 30/70 reads (43%) | called by muse, mutect2, varscan2
- TMEM121B | chr22:17121916 G>C | 5'Flank (SNP) | VAF 40/127 reads (31%) | called by muse, mutect2, varscan2
- TMEM242 | c.*1185T>G | 3'UTR (SNP) | VAF 47/69 reads (68%) | called by muse, mutect2, varscan2
- TOB2 | c.*2729A>T | 3'UTR (SNP) | VAF 99/236 reads (42%) | called by muse, mutect2, varscan2
- ZNF438 | c.*263C>A | 3'UTR (SNP) | VAF 10/48 reads (21%) | called by muse, mutect2, varscan2
- ZNF487 | c.*1125G>A | 3'UTR (SNP) | VAF 61/167 reads (37%) | called by muse, mutect2, varscan2
